Gene-level copy-number profile of tumor specimen TCGA-CX-7085-01A from TCGA case TCGA-CX-7085, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.3 years (28,221 days).
Specimen TCGA-CX-7085-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.210762a3-5e1a-4a15-93ed-9ea51952f2b1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CX-7085-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d1552d5e-fce2-47b6-9c31-55892e035a30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 59,704; copy number 3: 75; copy number 4: 28; copy number 5: 5; copy number 7: 7; copy number 8: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CX-7085-01A-21D-2010-01): tumor purity 0.19, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:77,157,207–77,433,388, 4 genes, copy number 7 (within-gene range 2–7): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr11:50,409,042–50,422,316, 1 gene, copy number 8: AC024405.1.
- chr12:114,077,133–114,113,489, 4 genes, copy number 5: AC010183.1, AC010183.2, HAUS8P1, GLULP5.
- chr16:7,726,841–7,726,951, 1 gene, copy number 5: AC005774.1.
- chr19:27,638,483–27,794,005, 3 genes, copy number 7 (within-gene range 2–7): ERVK-28, AC112702.1, LINC00662.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
